TCGA case TCGA-19-5958 — Glioblastoma Multiforme (TCGA-GBM)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Gliomas; Primary site: Brain; Tissue source site: Case Western. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/81622677-9742-40ea-ad60-5f9b2a624ea7

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Age at index: 56 years; Vital status: Dead; Days to death: 428 days (1.2 years).

Diagnoses (2)
1. Glioblastoma (the primary disease): ICD-O-3 morphology code: 9440/3; ICD-10 code: C71.9; Tissue or organ of origin: Brain, NOS; Site of resection or biopsy: Brain, NOS; Classification of tumor: primary; Age at diagnosis: 56.0 years (20,466 days); Year of diagnosis: 2010; Method of diagnosis: Surgical Resection; Prior treatment: No.
   Treatment given: Treatment type: Radiation, External Beam; Treatment intent type: Adjuvant; Days to treatment start: 34 days; Days to treatment end: 80 days; Treatment dose: 6,000 cGy; Course number: 1; Number of fractions: 30; Treatment anatomic sites: Primary Tumor Field.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Temozolomide; Treatment intent type: Adjuvant; Days to treatment start: 34 days; Days to treatment end: 80 days; Treatment dose: 6,090 mg; Prescribed dose: 145; Prescribed dose units: mg; Route of administration: Oral.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Bevacizumab; Treatment intent type: Adjuvant; Days to treatment start: 56 days; Days to treatment end: 265 days; Number of cycles: 15; Treatment outcome: Treatment Ongoing; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Temozolomide; Treatment intent type: Adjuvant; Days to treatment start: 111 days; Days to treatment end: 248 days; Number of cycles: 6; Treatment dose: 11,500 mg; Route of administration: Oral.
2. Recurrence of diagnosis 1 (Glioblastoma). Age at diagnosis: 57.0 years (20,822 days); Days to diagnosis: 356 days; Prior treatment: Yes.
   Treatment given: Treatment type: Surgery, NOS; Days to treatment start: 357 days.
   Recorded as not given: Pharmaceutical Therapy, NOS, for recurrent disease; Pharmaceutical Therapy, NOS; Radiation Therapy, NOS, for recurrent disease; Radiation Therapy, NOS.

Follow-up (4 entries)
- Days to follow up: 164 days; Disease response: Tumor Free.
- Day 356 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Locoregional; Days to recurrence: 356 days.
- Days to follow up: 428 days (1.2 years); Disease response: With Tumor.
- Karnofsky performance status: 80; Timepoint: Post Adjuvant Therapy.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-19-5958-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Longest dimension: 1.7; Intermediate dimension: 1; Shortest dimension: 1.
  Slide TCGA-19-5958-01A-01-BS1: Section location: Bottom; Percent tumor cells: 100; Percent tumor nuclei: 65; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 0.
  Slide TCGA-19-5958-01A-01-TS1: Section location: Top; Percent tumor cells: 100; Percent tumor nuclei: 70; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 0.
- Sample TCGA-19-5958-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-19-5958-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Histologic diagnosis: Untreated primary (de novo) GBM; History lgg diagnosis of brain tissue: No; Tumor status: Tumor free; History neoadjuvant treatment: No; Method initial path diagnosis: Tumor resection; Performance status timing: Post-Adjuvant Therapy.
- Drug treatment 1: Regimen number: 1; Pharmaceutical therapy drug name: Temodar.
- Drug treatment 1, Route of administrations: Route of administration: PO.
- Drug treatment 2: Regimen number: 3; Pharmaceutical therapy drug name: Avastin.
- Drug treatment 2, Route of administrations: Route of administration: IV.
- Drug treatment 3: Regimen number: 2; Pharmaceutical therapy drug name: Temodar.
- Follow-up form 2: Lost to follow-up: No; Treatment outcome first course: Progressive Disease; Treatment outcome at TCGA followup: Progressive Disease; Tumor status: With tumor.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: event (deceased), 428 days; disease-specific survival: event (death attributed to the disease, the Clinical Data Resource's approximation), 428 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 356 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-19-5958-01A-11D-1694-01): tumor purity 0.75, ploidy 2.02, whole-genome doublings 0.
